Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A1A5, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A1A5-01A (Primary Tumor).

[page 1 of 8]
166-0-3
Carcinoma, Urothelial, NOS 8120/3
Site Code: bladder, NOS C67.9

12/30/10
for

SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age: 79)

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

Bladder cancer, muscle invasive UCC

Specimens Submitted:

- 1: SP: Lymph node, cloquet; biopsy
- 2: SP: Lymph nodes, peri-vesicle; lymphadenectomy
- 3: SP: Ureter, right distal; resection
- 4: SP: Lymph nodes, left external iliac; lymphadenectomy
- 5: SP: Ureter, left distal; resection
- 6: SP: Bladder, prostate and seminal vesicles; radical cystoprostatectomy
- 7: SP: Lymph nodes, right common iliac; dissection
- 8: SP: Lymph nodes, right pelvic; dissection
- 9: SP: Lymph nodes, pre sacral; dissection
- 10: SP: Lymph nodes, left common iliac; dissection
- 11: SP: Lymph nodes, left pelvic; dissection
- 12: SP: Lymph nodes, left, "of marci"; lymphadenectomy
- 13: SP: Vas deferens, right; resection
- 14: SP: Vas deferens, left; resection
- 15: SP: Ureter, right; resection

DIAGNOSIS:

1. SP: Lymph node, cloquet; biopsy ()

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

2. SP: Lymph nodes, peri-vesicle; lymphadenectomy ()

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

3. SP: Ureter, right distal; resection ()

Benign segment of ureter

4. SP: Lymph nodes, left external iliac; lymphadenectomy ()

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

[page 2 of 8]
SURGICAL PATHOLOGY REPORT

5. SP: Ureter, left distal; resection () :
Benign segment of ureter

6. SP: Bladder, prostate and seminal vesicles; radical cystoprostatectomy () :

Tumor Type:
Invasive urothelial carcinoma, NOS

Histologic Grade:
High grade

Pattern of growth of the Non-Invasive component:
Flat (in situ carcinoma)

Pattern of growth of the Invasive component:
Infiltrating

Tumor Multicentricity:
Not identified

Bladder Local Invasion:
Deep half of muscularis propria

Extravesical Tumor Extension:
Ureters uninvolved
Urethra uninvolved

Vascular Invasion:
Identified

Perineural Invasion:
Identified

Surgical Margins:
Free of tumor

Non-Neoplastic Mucosa:
Exhibiting foreign body reaction

Prostate:
Nodular hyperplasia

Seminal Vesicles:
Not involved

Perivesical Lymph Nodes:
LN Not involved 1

The Pathologic Stage is (AJCC 2002):
pT2b (Invades deep half of muscularis propria)

PR0 (No involvement of prostate)

7. SP: Lymph nodes, right common iliac; dissection:

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 4

8. SP: Lymph nodes, right pelvic; dissection:

Lymph Node Dissection:

[page 3 of 8]
SURGICAL PATHOLOGY REPORT

Benign lymph nodes
Number of lymph nodes examined: 5

9. SP: Lymph nodes, pre sacral; dissection:

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 2

10. SP: Lymph nodes, left common iliac; dissection:

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 4

11. SP: Lymph nodes, left pelvic; dissection:

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 7

12. SP: Lymph nodes, left, "of marci"; lymphadenectomy:

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 2

13. SP: Vas deferens, right; resection:

Benign segment of vas deferens

14. SP: Vas deferens, left; resection:

Benign segment of vas deferens

15. SP: Ureter, right; resection:

Benign segment of ureter

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1).The specimen is received fresh for frozen diagnosis and labeled with "fragment of Cloquet node". It consists of a fragment of lymph node measuring 0.6 x 0.7 x 0.3 Cm. Entirely submitted.

Summary of sections:
FSC - frozen section control

[page 4 of 8]
SURGICAL PATHOLOGY REPORT

2). The specimen is received fresh for frozen diagnosis and labeled with "perivesical node". It consists of a lymph node measuring 1.2 x 0.3 x 0.3 cm. Entirely submitted.

Summary of sections:
FSC - frozen section control

3). The specimen is received fresh for frozen diagnosis and labeled with "right distal ureter". It consists of a fragment of tissue measuring 0.4 x 0.4 x 0.4 cm. Entirely submitted.

Summary of sections:
FSC - frozen section control

4). The specimen is received fresh for frozen diagnosis and labeled with "left external iliac node". It consists of a lymph node measuring 0.8 x 0.3 x 0.3 cm. Entirely submitted.

Summary of sections:
FSC - frozen section control, bisected

5). The specimen is received fresh for frozen diagnosis and labeled with "left distal ureter". It consists of a tubular tissue measuring 0.3 x 0.3 x 0.2 cm. Entirely submitted.

Summary of sections:
FSC - frozen section control

6) The specimen is received fresh labeled, "Bladder, prostate and seminal vesicles". It consists of a cystoprostatectomy with seminal vesicles measuring 9.6 cm from superior to inferior, 5.1 cm laterally and 6.2 cm from anterior to posterior. The left aspect of the bladder is inked blue and the right green. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal 2.5x1.9x0.4 cm tan-gray tumor, which is grossly situated within the posterior wall. The lesion measures 1.8 cm from the left orifice and 1.9 from the right. Both ureters are probe-patent measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal tan-white cut surface. Extension to the inked fat is grossly not identified. The remaining bladder mucosa is edematous. Discrete perivesical lymph nodes are grossly identified. The prostate is serially sectioned and is grossly remarkable. Representative sections are submitted including two sections from each prostatic quadrant and transition zone. TPS is submitted.

Summary of sections:
UTHM - urethral margin
RUM - right ureter margin
LUM - left ureter margin
L - lesion
TN - normal mucosa next to tumor
RUO - right ureter orifice (ureter is inked blue)
LUO - left ureter orifice (ureter is inked blue)
LP - left posterior wall
LA - left anterior wall
RP - right posterior wall
RA - right anterior wall
TRI - trigone
DOM - dome
RSV - right seminal vesicle
LSV - left seminal vesicle
RAP - right apex prostate

[page 5 of 8]
SURGICAL PATHOLOGY REPORT

LAP - left apex prostate
RAM - right anterior mid prostate
RPM - right posterior mid prostate
LAM - left anterior mid prostate
LPM - left posterior mid prostate
RAB - right anterior base prostate
RPB - right posterior base prostate
LAB - left anterior base prostate
LPB - left posterior base prostate
LN - perivesical lymph nodes

7). The specimen is received in formalin labeled "right common iliac nodes" and consists of multiple pink tan fatty lymph nodes with attached fatty fibrous tissue ranging from 0.4 cm up to 1.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
LN-lymph nodes
BLN-bisected lymph nodes

8). The specimen is received in formalin labeled "right pelvic nodes" and consists of multiple pink tan fatty lymph nodes with attached fatty fibrous tissue ranging from 0.3 cm up to 2.1 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
LN-lymph nodes
BLN-bisected lymph nodes

9). The specimen is received in formalin labeled "presacral node" and consists of multiple pink tan fatty lymph nodes with attached fatty fibrous tissue ranging from 0.3 cm up to 1.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
LN-lymph nodes
BLN-bisected lymph nodes

10). The specimen is received in formalin labeled "left common iliac node" and consists of multiple pink tan lymph nodes with attached fatty fibrous tissue ranging from 0.3 cm up to 1.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
LN-lymph nodes
BLN-bisected lymph nodes

11). The specimen is received in formalin labeled "Left pelvic nodes" and consists of multiple pink tan fatty lymph nodes with attached fatty fibrous tissue ranging from 0.5 cm up to 1.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
LN-lymph nodes
BLN-bisected lymph nodes

[page 6 of 8]
SURGICAL PATHOLOGY REPORT

12). The specimen is received fresh, labeled "left testis", and consists of multiple of lymphoid soft tissue fragment measuring 2.2 x 2.1 x 0.2 cm in aggregate, which is entirely submitted.

Summary of sections:

U - undesignated

13. The specimen is received in formalin labeled, "Right vas deferens", and consists of one portion of vas deferens measuring 4.5 cm in length and 0.5 cm in diameter. Representative section of the specimen is submitted

Summary of sections:

RS - representative section

14. The specimen is received in formalin labeled, "Left vas deferens", and consists of one portion of vas deferens measuring 6 cm in length and 0.5 cm in diameter. Representative section of the specimen is submitted.

Summary of sections:

RS - representative section

15. The specimen is received in formalin labeled, "Right ureter", and consists of one segment of ureter measuring 1.8 cm in length and 0.5 cm in diameter. Entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Lymph node, cloquet; biopsy

Block	Sect. Site	PCs
1	FSC	1

Part 2: SP: Lymph nodes, peri- vesicle; lymphadenectomy "

Block	Sect. Site	PCs
1	FSC	1

Part 3: SP: Ureter, right distal; resection (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 4: SP: Lymph nodes, left external iliac; lymphadenectomy "

Block	Sect. Site	PCs
1	FSC	1

Part 5: SP: Ureter, left distal; resection (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 6: SP: Bladder, prostate and seminal vesicles; radical cystoprostatectomy (

Block	Sect. Site	PCs
-------	------------	-----

[page 7 of 8]
SURGICAL PATHOLOGY REPORT

1	DOM	1
1	FSC	1
6	L	6
1	L SV	1
1	LA	1
1	LAB	1
1	LAM	1
1	LAP	1
1	LN	1
1	LP	1
1	LPB	1
1	LPM	1
1	LUM	1
1	LUO	1
1	RA	1
1	RAB	1
1	RAM	1
1	rap	1
1	RP	1
1	RPB	1
1	RPM	1
1	RSV	1
2	RUO	2
1	TN	1
1	TRI	1

Part 7: SP: Lymph nodes, right common iliac; dissection

Block	Sect. Site	PCs
2	BLN	2
1	LN	1

Part 8: SP: Lymph nodes, right pelvic; dissection

Block	Sect. Site	PCs
4	BLN	4
2	LN	2

Part 9: SP: Lymph nodes, pre sacral; dissection

Block	Sect. Site	PCs
3	BLN	3
1	LN	1

Part 10: SP: Lymph nodes, left common iliac; dissection

Block	Sect. Site	PCs
1	BLN	1
1	LN	1

Part 11: SP: Lymph nodes, left pelvic; dissection

Block	Sect. Site	PCs
2	BLN	3
1	LN	1

Part 12: SP: Lymph nodes, left, "of marci"; lymphadenectomy

Block	Sect. Site	PCs
1	U	1

[page 8 of 8]
SURGICAL PATHOLOGY REPORT

Part 13: SP: Vas deferens, right; resection

Block 1 Sect. Site RS PCs 1

Part 14: SP: Vas deferens, left; resection

Block 1 Sect. Site RS PCs 1

Part 15: SP: Ureter, right; resection

Block 1 Sect. Site U PCs 1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: FRAGMENT OF CLOQUET NODES (BENIGN LYMPH NODE
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: SP: PERIVESICLES NODES (BENIGN LYMPH NODE
PERMANENT DIAGNOSIS: SAME
- 3) FROZEN SECTION DIAGNOSIS: SP: RIGHT DISTAL URETER BENIGN
PERMANENT DIAGNOSIS: SAME
- 4) FROZEN SECTION DIAGNOSIS: SP: LEFT EXTERNAL ILIAC NODES (FS): BENIGN LYMPH NODE
PERMANENT DIAGNOSIS: SAME
- 5) FROZEN SECTION DIAGNOSIS: SP: LEFT DISTAL URETER (): BENIGN
PERMANENT DIAGNOSIS: SAME
- 6) FROZEN SECTION DIAGNOSIS: SP: BLADDER, PROSTATE AND SEMINAL VESICLES (): THE URETHRAL
MARGIN IS BENIGN (WEN).
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file a6e5e485-283c-4f12-af36-cb9571d0bce3 (TCGA-DK-A1A5.07970DA4-6136-48BA-BCA4-3ACC8C3DC1E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).